TCGA case TCGA-22-5491 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4cdeafe4-a6db-498f-a019-6e3a9dc35b2f

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 74 years; Vital status: Dead; Days to death: 1,713 days (4.7 years).

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 74.3 years (27,145 days); Year of diagnosis: 2003; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.

Follow-up (2 entries)
- Karnofsky performance status: 0.
- Follow-up contact recording only the day: day 1,713.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 57.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-22-5491-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.7; Shortest dimension: 0.2.
  Slide TCGA-22-5491-01A-01-TS1: Section location: Top; Percent tumor cells: 74; Percent tumor nuclei: 80; Percent normal cells: 13; Percent necrosis: 13; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-22-5491-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-22-5491-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.5; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); Days to last known alive: 7; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tobacco smoking history indicator: 2; Anatomic organ subdivision: L-Lower; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,713 days; disease-specific survival: event status not recorded, 1,713 days; progression-free interval: no event (censored), 1,713 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-22-5491-01A-01D-1631-01): tumor purity 0.67, ploidy 3.59, whole-genome doublings 1.
